TARGET case TARGET-30-PAKACY — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/c6e269a7-d067-5990-815b-6f5d0c5155c0

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Age at diagnosis: 3.0 years (1,114 days); Year of diagnosis: 1994; Days to last follow up: 1,366 days (3.7 years); INSS stage: Stage 4.

Biospecimens (1 sample)
- Sample TARGET-30-PAKACY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
